Somatic mutation profile of tumor specimen MMRF_2511_1_BM_CD138pos (aliquot MMRF_2511_1_BM_CD138pos_T1_KHS5U_L12893) from MMRF case MMRF_2511, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.8 years (23,289 days).
Specimen MMRF_2511_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9999ee7f-b57f-4566-9303-909b1982979c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2511_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2511_1_PB_Whole_C2_KHS5U_L12894; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dda87f67-215d-4011-9f0e-9f9370401c76

The open-access MAF lists 67 somatic variants for this specimen: 24 protein-altering or splice-affecting, 6 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, 3'UTR 16, Intron 11, Silent 6, 5'UTR 4, 5'Flank 3, RNA 2, Splice Site 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 70/191 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKAP6 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 272/663 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1177733503; called by muse, mutect2, varscan2
- ATP1A3 | c.1311G>T p.K437N (on ENST00000545399 / NM_001256214.2; = p.K424N on NM_152296.5) | Missense Mutation (SNP) | VAF 124/454 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.262); catalogued as COSV100132511; called by muse, mutect2, varscan2
- C19orf44 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 138/274 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as rs749553167; called by muse, mutect2, varscan2
- CDH11 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.063); catalogued as rs527451513, COSV51769963; called by muse, mutect2, varscan2
- DMD | c.6788del p.R2263Pfs*8 | Frame Shift Del (DEL) | VAF 121/177 reads (68%) | catalogued as COSV58891999; called by mutect2, pindel, varscan2
- GPLD1 | c.2035G>A p.V679M | Missense Mutation (SNP) | VAF 101/175 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57759706; called by muse, mutect2, varscan2
- IGF2BP1 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.654); catalogued as rs531902165, COSV99288311; called by muse, mutect2, varscan2
- IGHV2-70 | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 128/310 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as rs369066675; called by muse, varscan2
- IGKV4-1 | c.161A>C p.N54T | Missense Mutation (SNP) | VAF 72/80 reads (90%) | SIFT tolerated (0.2); PolyPhen benign (0.065); catalogued as rs374142442; called by muse, mutect2, varscan2
- NUP85 | c.1089G>T p.E363D | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.041); catalogued as rs750613625; called by muse, mutect2, varscan2
- SLITRK3 | c.2330G>C p.R777P | Missense Mutation (SNP) | VAF 39/326 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.053); catalogued as rs754951557, COSV53847041; called by muse, mutect2, varscan2
- STAT5A | c.611T>G p.L204R | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs745891584; called by muse, mutect2, varscan2
- ACAD11 | c.788T>G p.F263C | Missense Mutation (SNP) | VAF 13/317 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2
- EHMT1 | c.2813A>C p.H938P | Missense Mutation (SNP) | VAF 71/268 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM186A | c.2075A>C p.D692A | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- NT5DC1 | c.437T>C p.L146S | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- PAX5 | c.601_604+1del p.X201_splice | Splice Site (DEL) | VAF 64/132 reads (48%) | called by mutect2, pindel, varscan2
- PREX1 | c.2260G>C p.V754L | Missense Mutation (SNP) | VAF 59/241 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RIPOR3 | c.15G>C p.L5F | Missense Mutation (SNP) | VAF 190/426 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- SACS | c.13073A>C p.E4358A | Missense Mutation (SNP) | VAF 130/278 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SLC25A27 | c.8T>C p.V3A | Missense Mutation (SNP) | VAF 149/340 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- UNC80 | c.4121T>G p.L1374W | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.847); called by mutect2, varscan2
- VPS18 | c.2668T>C p.Y890H | Missense Mutation (SNP) | VAF 63/138 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCND1 | c.105G>A p.E35= | Silent (SNP) | VAF 130/238 reads (55%) | catalogued as rs1212798981; called by muse, mutect2, varscan2
- DBX2 | c.777T>C p.G259= | Silent (SNP) | VAF 73/156 reads (47%) | called by muse, mutect2, varscan2
- FBXL17 | c.708C>T p.G236= | Silent (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- MN1 | c.2013C>T p.G671= | Silent (SNP) | VAF 78/166 reads (47%) | called by muse, mutect2, varscan2
- SHH | c.1218C>T p.R406= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV51918503; called by muse, mutect2, varscan2
- SHISA6 | c.177C>T p.N59= | Silent (SNP) | VAF 36/63 reads (57%) | called by muse, mutect2, varscan2
- BTBD3 | c.327-87G>T | Intron (SNP) | VAF 178/380 reads (47%) | called by muse, mutect2, varscan2
- C10orf67 | c.*63T>C | 3'UTR (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- CACNG8 | c.*233T>G | 3'UTR (SNP) | VAF 39/85 reads (46%) | catalogued as rs552128309; called by muse, mutect2, varscan2
- CPSF4 | c.404-16A>G | Intron (SNP) | VAF 68/138 reads (49%) | called by muse, mutect2, varscan2
- CTSC | c.319-9514G>A | Intron (SNP) | VAF 157/314 reads (50%) | called by muse, mutect2, varscan2
- DGKB | c.*1780T>G | 3'UTR (SNP) | VAF 37/83 reads (45%) | called by muse, mutect2, varscan2
- FOLH1B | n.522-106G>A | Intron (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2
- GMPPB | c.-211C>T | 5'UTR (SNP) | VAF 16/184 reads (9%) | called by muse, mutect2
- H3C13 | c.*35_*36del | 3'UTR (DEL) | VAF 170/394 reads (43%) | catalogued as rs1553754831; called by mutect2, varscan2
- IARS1 | c.*453A>G | 3'UTR (SNP) | VAF 29/64 reads (45%) | called by muse, mutect2, varscan2
- IGHJ6 | chr14:105863432 A>T | 5'Flank (SNP) | VAF 12/21 reads (57%) | catalogued as rs549454719; called by muse, varscan2
- L3MBTL4 | c.1471+15410C>A | Intron (SNP) | VAF 57/117 reads (49%) | called by muse, mutect2, varscan2
- LCP2 | c.*1213G>A | 3'UTR (SNP) | VAF 46/96 reads (48%) | catalogued as rs374901869; called by muse, mutect2, varscan2
- LPAR1 | chr9:110873868 C>T | 3'Flank (SNP) | VAF 57/131 reads (44%) | catalogued as rs573524144; called by muse, mutect2, varscan2
- LTB | c.163-57G>C | Intron (SNP) | VAF 284/628 reads (45%) | called by muse, mutect2, varscan2
- MALAT1 | n.40C>G | RNA (SNP) | VAF 84/184 reads (46%) | called by muse, mutect2
- MALAT1 | n.42T>A | RNA (SNP) | VAF 87/186 reads (47%) | called by muse, mutect2
- MIR5195 | chr14:106851250 G>A | 5'Flank (SNP) | VAF 135/310 reads (44%) | catalogued as rs747274438; called by muse, varscan2
- MIR5195 | chr14:106851321 A>C | 5'Flank (SNP) | VAF 105/248 reads (42%) | catalogued as rs1440026460; called by muse, varscan2
- MRPS33 | c.*127T>G | 3'UTR (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- MRTFB | c.155-23304C>A | Intron (SNP) | VAF 35/92 reads (38%) | called by muse, mutect2, varscan2
- NAA60 | c.-221C>T | 5'UTR (SNP) | VAF 32/46 reads (70%) | called by muse, mutect2, varscan2
- NRXN1 | c.-695G>A | 5'UTR (SNP) | VAF 83/180 reads (46%) | catalogued as rs1314353087; called by muse, mutect2, varscan2
- NUDT16 | c.*2126G>A | 3'UTR (SNP) | VAF 71/161 reads (44%) | called by muse, mutect2, varscan2
- NUP43 | c.-10C>T | 5'UTR (SNP) | VAF 225/461 reads (49%) | catalogued as rs752630671, COSV61190026; called by muse, mutect2, varscan2
- PCGF3 | c.110-365C>T | Intron (SNP) | VAF 10/20 reads (50%) | catalogued as rs893507197; called by muse, mutect2, varscan2
- PTPRF | c.3974-161G>A | Intron (SNP) | VAF 17/52 reads (33%) | catalogued as rs1201165573; called by muse, mutect2, varscan2
- RSF1 | c.*4727A>G | 3'UTR (SNP) | VAF 35/77 reads (45%) | called by muse, mutect2, varscan2
- SEMA4C | c.110-252G>A | Intron (SNP) | VAF 12/156 reads (8%) | catalogued as rs1301299397; called by muse, mutect2
- SLFN11 | c.*373T>C | 3'UTR (SNP) | VAF 63/125 reads (50%) | called by muse, mutect2, varscan2
- STX12 | c.*434G>C | 3'UTR (SNP) | VAF 29/158 reads (18%) | called by muse, mutect2, varscan2
- TAT | c.*2228G>A | 3'UTR (SNP) | VAF 45/100 reads (45%) | called by muse, mutect2, varscan2
- TK2 | c.31+144G>C | Intron (SNP) | VAF 80/246 reads (33%) | catalogued as rs781512555; called by muse, mutect2, varscan2
- UNC13A | c.*275T>C | 3'UTR (SNP) | VAF 80/270 reads (30%) | called by muse, mutect2, varscan2
- WASF3 | c.*2368A>G | 3'UTR (SNP) | VAF 5/96 reads (5%) | called by muse, mutect2
- WDR37 | c.*2522A>G | 3'UTR (SNP) | VAF 28/94 reads (30%) | catalogued as rs1221375664; called by muse, mutect2, varscan2
- ZNF648 | c.*1429T>G | 3'UTR (SNP) | VAF 56/119 reads (47%) | catalogued as rs1029520225; called by muse, mutect2, varscan2
